CCDI case PBCBRT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/5df05c49-ada7-4b51-abdb-5e10ea40db12

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Soft tissue tumor, benign: ICD-O-3 morphology code: 8800/0; Tissue or organ of origin: Spinal cord; Age at diagnosis: 17.4 years (6,357 days).

Biospecimens (3 samples)
- Sample 0DNJA5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNJAW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNJBB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
